Somatic mutation profile of tumor specimen C3N-00169-03 (aliquot CPT0014860009) from CPTAC case C3N-00169, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.5 years (21,005 days).
Specimen C3N-00169-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc696545-795a-4ce0-bf59-31c68567eaef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00169-31 (Blood Derived Normal), aliquot CPT0016620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40fd346d-d2a1-42a7-b8aa-e7c27c572fec

The open-access MAF lists 247 somatic variants for this specimen: 171 protein-altering or splice-affecting, 39 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 39, Intron 20, Nonsense Mutation 15, Frame Shift Del 6, 3'UTR 6, RNA 5, 5'UTR 4, Frame Shift Ins 2, Splice Site 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 66/234 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 53/194 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4460G>A p.R1487H | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs754289848, COSV58131792; called by muse, mutect2, varscan2
- APCS | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54817515, COSV54817666; called by muse, mutect2, varscan2
- ARHGEF10L | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs144936441, COSV63423266; called by muse, mutect2, varscan2
- BMX | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 37/174 reads (21%) | catalogued as COSV59592677; called by muse, mutect2, varscan2
- BRINP1 | c.1116C>A p.H372Q | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.88); catalogued as rs370368536; called by muse, mutect2, varscan2
- C2orf78 | c.1441A>C p.K481Q | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as rs780052547; called by muse, mutect2, varscan2
- CACNA1H | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 24/189 reads (13%) | catalogued as rs970648879; called by muse, mutect2, varscan2
- CEP170B | c.881G>A p.R294H (on ENST00000453495; = p.R223H on NM_015005.3) | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs199932976; called by muse, mutect2, varscan2
- CFAP99 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746898256; called by muse, mutect2, varscan2
- COCH | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 39/328 reads (12%) | catalogued as rs371802597; called by muse, mutect2, varscan2
- COL22A1 | c.4576G>T p.G1526W | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1252891396, COSV57362172; called by muse, mutect2, varscan2
- COL22A1 | c.1865C>A p.P622H | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs948354747; called by muse, mutect2, varscan2
- COLCA2 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 52/319 reads (16%) | catalogued as COSV67695186, COSV67695274; called by muse, mutect2, varscan2
- CSF1R | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53845085; called by muse, mutect2, varscan2
- CWH43 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245526570; called by muse, mutect2, varscan2
- DMD | c.10102G>T p.D3368Y | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM070895, CM140178, COSV100628622; called by muse, mutect2, varscan2
- DMP1 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56820053; called by muse, mutect2, varscan2
- EHMT1 | c.3569G>T p.R1190L | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66044676; called by muse, mutect2, varscan2
- FAM3D | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as rs778478340; called by muse, mutect2
- FHOD3 | c.1520G>C p.R507T (on ENST00000359247 / NM_001281739.3; = p.R524T on NM_025135.5) | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57170601; called by muse, mutect2, varscan2
- GABRG1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.911); catalogued as rs1334218998, COSV99777487; called by muse, mutect2, varscan2
- GALR1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.054); catalogued as rs929449672; called by muse, mutect2, varscan2
- GDF3 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470277131, COSV61712059; called by muse, mutect2, varscan2
- GLRB | c.479A>T p.N160I | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766014355; called by muse, mutect2, varscan2
- GSDME | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs559632895; called by muse, mutect2, varscan2
- HSPA4L | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1444916011, COSV56546993; called by muse, mutect2, varscan2
- HTR5A | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775005765; called by muse, mutect2
- IGSF10 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 44/252 reads (17%) | catalogued as COSV56791117; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1787T>C p.L596P | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.467); catalogued as rs1227164102; called by muse, mutect2, varscan2
- KIF21B | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59766970; called by muse, mutect2, varscan2
- KIF3B | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV65228902; called by muse, mutect2, varscan2
- KMT2A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63288160; called by muse, mutect2
- LINGO1 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752005315, COSV62436319; called by muse, mutect2, varscan2
- MARF1 | c.4379C>T p.T1460I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as COSV60029210; called by muse, mutect2, varscan2
- MASP1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99397462; called by muse, varscan2
- MASP1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99397137; called by muse, varscan2
- MTUS2 | c.2352G>T p.R784S | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70916591, COSV70916620; called by muse, mutect2, varscan2
- NCAPG2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418337253; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2, varscan2
- OR2T33 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 35/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817995; called by muse, mutect2, varscan2
- OR2T34 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1424135399, COSV100170395; called by muse, mutect2, varscan2
- P2RY13 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56369321; called by muse, mutect2, varscan2
- PCDH7 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1177378448; called by muse, mutect2
- PKP1 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as COSV99824980; called by muse, mutect2, varscan2
- PPP1R3A | c.1862G>T p.R621I | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV52885310, COSV52886773; called by muse, mutect2, varscan2
- RP1L1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749757188; called by muse, mutect2, varscan2
- RXFP3 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 50/637 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778264518; called by muse, mutect2
- SCML4 | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV100940390; called by muse, mutect2, varscan2
- SEMA6D | c.2434A>G p.S812G (on ENST00000316364 / NM_153618.2; = p.S750G on NM_020858.2) | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.837); catalogued as rs1483806899, COSV60375943; called by muse, varscan2
- SLC29A4 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.914); catalogued as rs763353103; called by muse, mutect2
- SLC39A11 | c.898G>A p.G300S (on ENST00000542342 / NM_001159770.2; = p.G293S on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776994238, COSV99723745; called by muse, mutect2, varscan2
- SLC39A12 | c.2035C>T p.L679F (on ENST00000377369 / NM_001145195.2; = p.L642F on NM_152725.3) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101070116; called by muse, mutect2, varscan2
- SLCO1B1 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1307367466; called by muse, mutect2, varscan2
- SOX8 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53510683; called by muse, mutect2
- TBC1D26 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 70/404 reads (17%) | catalogued as rs749678463, COSV68610560; called by mutect2, varscan2
- TLR7 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV66123662; called by muse, mutect2, varscan2
- TPM3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 385/930 reads (41%) | catalogued as COSV55139343; called by muse, mutect2, varscan2
- TRAF6 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61923320; called by muse, mutect2, varscan2
- TRPS1 | c.938G>C p.G313A (on ENST00000220888 / NM_001330599.2; = p.G326A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.293); catalogued as COSV55266393; called by muse, mutect2
- TTC3 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61288559; called by muse, mutect2, varscan2
- USP13 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1455743710; called by muse, mutect2, varscan2
- VEGFC | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54596751, COSV54603187; called by muse, mutect2, varscan2
- XRN1 | c.4797C>A p.H1599Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1179850369; called by muse, mutect2, varscan2
- ABCC5 | c.1534C>A p.L512M | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY2 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ADCY5 | c.797T>A p.L266H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ADGRL3 | c.3898C>G p.P1300A | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, varscan2
- AGO2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- AGTPBP1 | c.958C>G p.L320V (on ENST00000357081 / NM_001330701.2; = p.L372V on NM_001286715.1) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- AGTR2 | c.934T>A p.C312S | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AL031315.1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- ALG8 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANK3 | c.11476G>T p.V3826F | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPM | c.7840G>C p.D2614H | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- B4GALNT4 | c.1559A>C p.Q520P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BHLHE23 | c.318C>A p.N106K (on ENST00000370346; = p.N122K on NM_080606.4) | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCBE1 | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CCDC57 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDIN1 | c.368G>T p.S123I (on ENST00000437989; = p.S25I on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CEP350 | c.4061G>T p.G1354V | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- CERKL | c.810_831del p.L271Gfs*8 (on ENST00000339098 / NM_001030311.2; = p.L245Gfs*8 on NM_201548.5) | Frame Shift Del (DEL) | VAF 64/390 reads (16%) | called by mutect2, pindel
- CFAP46 | c.2393G>T p.W798L | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CFAP47 | c.7686+1G>T p.X2562_splice | Splice Site (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- COL19A1 | c.790del p.V264* | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- COLGALT2 | c.647del p.P216Qfs*25 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- CTNND1 | c.2896-4A>G | Splice Region (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- DCDC2C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DDX42 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 98/450 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- EPB41L1 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 66/466 reads (14%) | called by muse, mutect2, varscan2
- F12 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 125/461 reads (27%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FAT3 | c.2926G>T p.V976F | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FBH1 | c.1139T>A p.V380D (on ENST00000362091 / NM_178150.3; = p.V431D on NM_032807.4) | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FHOD3 | c.1788G>T p.E596D (on ENST00000359247 / NM_001281739.3; = p.E613D on NM_025135.5) | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FLG | c.7259C>A p.T2420N | Missense Mutation (SNP) | VAF 331/956 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FOXD1 | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 101/597 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FSIP2 | c.14234C>A p.P4745Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GABRA2 | c.1285T>A p.F429I | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GBX2 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GIMAP4 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GOLGA3 | c.3095del p.G1032Afs*38 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel
- GRID2IP | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- GRIK3 | c.2720G>C p.S907T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCJ | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH2 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KCNH5 | c.713T>A p.F238Y | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNU1 | c.2575G>C p.V859L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIAA1549L | c.938C>T p.P313L (on ENST00000321505; = p.P610L on NM_012194.3) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIDINS220 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- KRT75 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LCOR | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- LRRN2 | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LURAP1 | c.596_597del p.W199* | Frame Shift Del (DEL) | VAF 38/215 reads (18%) | called by mutect2, pindel, varscan2
- MAP3K15 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MMRN1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMRN1 | c.109A>T p.K37* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- MRC1 | c.2366C>A p.P789Q | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MRPL39 | c.450G>C p.M150I | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- MTUS2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- MTUS2 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.397); called by muse, varscan2
- NEU3 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 35/217 reads (16%) | called by muse, mutect2, varscan2
- NHLH1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NMT2 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- NTNG1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NTS | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4C3 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- P2RY10 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH7 | c.1167C>G p.D389E | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHAC1 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PCDHB3 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PGLYRP4 | c.542A>T p.H181L | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PHF3 | c.4637G>A p.G1546E | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3C2A | c.2770C>T p.L924F | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PLCB1 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROSER3 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMB7 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 37/193 reads (19%) | called by muse, mutect2, varscan2
- RBM15B | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RHBDL3 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF31 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.8747C>T p.S2916F | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SEMA3E | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SLC4A10 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SLC9B2 | c.944C>G p.A315G | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SLITRK2 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 65/162 reads (40%) | called by muse, mutect2, varscan2
- SMO | c.248_253del p.L83_Y85delinsH | In Frame Del (DEL) | VAF 61/319 reads (19%) | called by mutect2, pindel, varscan2
- SNX19 | c.2263G>T p.E755* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2
- SP5 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, varscan2
- TCFL5 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- TEX13A | c.660del p.M221Wfs*132 | Frame Shift Del (DEL) | VAF 44/127 reads (35%) | called by mutect2, pindel, varscan2
- THAP4 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- THSD7B | c.3641G>C p.C1214S (on ENST00000272643; = p.C1212S on NM_001316349.2) | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM151A | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TNIP2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- TNNC2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- TPRA1 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAJ52 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TRIM51 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TTN | c.78205dup p.E26069Gfs*9 (on ENST00000591111; = p.E18645Gfs*9 on NM_003319.4) | Frame Shift Ins (INS) | VAF 46/207 reads (22%) | called by mutect2, pindel, varscan2
- UGT2B11 | c.1076A>G p.Q359R | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- VWA5A | c.1448T>A p.M483K | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.191); called by muse, mutect2
- XIRP2 | c.1028dup p.S344Qfs*2 (on ENST00000628543; = p.S519Qfs*2 on NM_152381.6) | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | called by pindel, varscan2
- XRN1 | c.1737G>T p.E579D | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZBBX | c.1594T>A p.L532M | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ZBBX | c.1592C>A p.T531N | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- ZNF254 | c.30+1G>T p.X10_splice | Splice Site (SNP) | VAF 46/207 reads (22%) | called by muse, mutect2, varscan2
- ZNF469 | c.5048A>T p.E1683V (on ENST00000437464; = p.E1711V on NM_001367624.2) | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF560 | c.891T>A p.Y297* | Nonsense Mutation (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1301G>T p.G434V (on ENST00000544604 / NM_001206998.2; = p.G334V on NM_032173.3) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ZP4 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRE1 | c.1212C>A p.V404= | Silent (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2721C>A p.L907= (on ENST00000506720 / NM_001322402.2; = p.L839= on NM_015236.6) | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV72231202; called by muse, mutect2, varscan2
- ALDH3B2 | c.558C>A p.T186= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- AMIGO3 | c.888G>A p.L296= | Silent (SNP) | VAF 42/315 reads (13%) | catalogued as rs1466765082, COSV57537573; called by muse, mutect2, varscan2
- AUTS2 | c.3223T>C p.L1075= | Silent (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- CROCC2 | c.3214C>A p.R1072= | Silent (SNP) | VAF 60/317 reads (19%) | catalogued as COSV101376394; called by muse, mutect2, varscan2
- DCAF12L2 | c.882A>C p.T294= | Silent (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- FAM83B | c.1740C>A p.V580= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- FAT2 | c.354C>T p.I118= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV55819361; called by muse, mutect2, varscan2
- FBN1 | c.2907G>C p.L969= | Silent (SNP) | VAF 91/286 reads (32%) | called by muse, mutect2, varscan2
- FREM3 | c.3381A>T p.S1127= | Silent (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- IFT140 | c.1872G>C p.T624= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs775156902, COSV68486509, COSV68493846; called by muse, mutect2
- IKZF1 | c.63C>T p.S21= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs777664112; called by muse, mutect2, varscan2
- IRGC | c.723C>T p.R241= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- KLHL34 | c.789C>A p.S263= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- LZTS3 | c.1242G>T p.R414= (on ENST00000329152; = p.R368= on NM_001282533.2) | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- MTHFR | c.1950G>A p.A650= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as rs1300052327, COSV100453543; called by muse, mutect2, varscan2
- MTUS2 | c.1935C>T p.I645= | Silent (SNP) | VAF 25/241 reads (10%) | called by muse, varscan2
- NCAN | c.3756T>C p.H1252= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs372077588; called by muse, mutect2, varscan2
- NLRP7 | c.1215C>G p.G405= | Silent (SNP) | VAF 136/389 reads (35%) | catalogued as COSV100053476; called by muse, mutect2, varscan2
- OR4A16 | c.360C>T p.R120= | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- OR4C16 | c.219T>A p.T73= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- OR51Q1 | c.294C>A p.A98= | Silent (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2
- OR8I2 | c.495T>C p.S165= | Silent (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- PCDHGB3 | c.1272T>A p.A424= | Silent (SNP) | VAF 96/293 reads (33%) | called by muse, mutect2, varscan2
- PRLR | c.300C>A p.I100= | Silent (SNP) | VAF 72/331 reads (22%) | catalogued as COSV51500554; called by muse, mutect2, varscan2
- PTPRM | c.2259C>T p.F753= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as rs749263983, COSV59848593; called by muse, mutect2, varscan2
- RAB27B | c.525A>G p.E175= | Silent (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- SAG | c.853C>T p.L285= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs767748858; called by muse, mutect2, varscan2
- SCN8A | c.2463C>T p.D821= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs773865400, COSV61978194; ClinVar: likely benign; called by muse, mutect2, varscan2
- SGSM2 | c.1938C>T p.I646= (on ENST00000426855 / NM_001098509.2; = p.I691= on NM_014853.3) | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- SSB | c.978A>T p.L326= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV99641802; called by muse, mutect2, varscan2
- STRADA | c.192A>T p.P64= (on ENST00000336174 / NM_001363786.1; = p.P27= on NM_153335.6) | Silent (SNP) | VAF 53/276 reads (19%) | called by muse, mutect2, varscan2
- TMEM150B | c.690G>T p.P230= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV100442359; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1674C>G p.P558= | Silent (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- XPR1 | c.1560C>T p.I520= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, varscan2
- ZFR | c.279T>C p.A93= | Silent (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- ZNF695 | c.996C>T p.V332= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV60584783; called by muse, mutect2, varscan2
- ZNF716 | c.1188T>A p.T396= | Silent (SNP) | VAF 68/296 reads (23%) | called by muse, varscan2
- AC093155.3 | c.767-910C>A | Intron (SNP) | VAF 29/189 reads (15%) | catalogued as COSV63352643; called by muse, mutect2, varscan2
- ACVRL1 | c.1049-45C>A | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs1486787880; called by muse, mutect2, varscan2
- AHI1 | c.*5T>C | 3'UTR (SNP) | VAF 41/142 reads (29%) | catalogued as rs751910136; called by muse, mutect2, varscan2
- ASTN2 | c.*259del | 3'UTR (DEL) | VAF 63/322 reads (20%) | catalogued as rs748885051; called by mutect2, pindel, varscan2
- CAMK2B | c.1339+9C>A | Intron (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- CASS4 | c.1953+12G>T | Intron (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- CD46 | c.947-17C>G | Intron (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- CD5L | c.*35C>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by mutect2, varscan2
- COILP1 | n.228G>C | RNA (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- COL6A6 | c.4533+23G>A | Intron (SNP) | VAF 24/99 reads (24%) | catalogued as COSV62026429; called by muse, mutect2, varscan2
- DCN | c.211+5531T>G | Intron (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- DTNA | c.1662+2084C>T | Intron (SNP) | VAF 11/268 reads (4%) | catalogued as rs1243856272; called by muse, mutect2
- DZIP1 | c.686-695C>A | Intron (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- EYS | c.1767-7276C>A | Intron (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- F11 | c.*17del | 3'UTR (DEL) | VAF 64/338 reads (19%) | catalogued as COSV99250958; called by mutect2, pindel, varscan2
- FAM13C | c.508-21T>A | Intron (SNP) | VAF 51/196 reads (26%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5416C>T | Intron (SNP) | VAF 52/190 reads (27%) | catalogued as rs1408163485; called by muse, varscan2
- GALNT2 | c.*471C>T | 3'UTR (SNP) | VAF 79/312 reads (25%) | catalogued as rs1449442497; called by muse, mutect2, varscan2
- GLIPR2 | c.*11G>T | 3'UTR (SNP) | VAF 71/308 reads (23%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+74749G>T | Intron (SNP) | VAF 49/253 reads (19%) | catalogued as rs768639300; called by muse, mutect2, varscan2
- LINC01949 | n.1142G>T | RNA (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- LRRC37A5P | n.291C>T | RNA (SNP) | VAF 66/287 reads (23%) | catalogued as rs1203220513; called by muse, mutect2, varscan2
- LRTOMT | c.438-21C>T | Intron (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- MECOM | c.-189-1202_-189-1195del | Intron (DEL) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- MIIP | c.715+16C>T | Intron (SNP) | VAF 22/165 reads (13%) | catalogued as rs775716183; called by muse, mutect2, varscan2
- MIR1269A | n.46G>T | RNA (SNP) | VAF 34/195 reads (17%) | catalogued as rs1357039529; called by muse, mutect2, varscan2
- NR2C2 | c.-18C>T | 5'UTR (SNP) | VAF 25/244 reads (10%) | catalogued as rs749305587; called by muse, mutect2, varscan2
- OACYLP | n.867G>T | RNA (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- PAX6 | c.1033-63G>T | Intron (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-1305G>T | Intron (SNP) | VAF 69/296 reads (23%) | called by muse, mutect2, varscan2
- PRSS1 | c.201-53T>A | Intron (SNP) | VAF 46/210 reads (22%) | catalogued as rs745503927; called by muse, mutect2, varscan2
- SHCBP1L | chr1:182953251 C>G | 5'Flank (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- SLC25A48 | chr5:135888034 G>T | 3'Flank (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-196C>A | 5'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- TBC1D19 | c.1506+26G>T | Intron (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- ZNF492 | c.-17A>T | 5'UTR (SNP) | VAF 72/215 reads (33%) | catalogued as rs746614640; called by muse, mutect2, varscan2
- ZNF729 | c.-31A>T | 5'UTR (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
